Somatic mutation profile of tumor specimen 0DS4KI from CCDI case PBCHJA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.3 years (5,970 days).
Specimen 0DS4KI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01a67c5c-1784-4d2c-887e-996ce262e409.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS4KJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f9b9d62-6f5f-4f8e-bb96-d9e03dbb9db7

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1914_1916dup p.T639dup (on ENST00000288602 / NM_001374244.1; = p.T599dup on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 53/519 reads (10%) | catalogued as rs727502902; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AC053503.6 | c.548C>A p.S183* | Nonsense Mutation (SNP) | VAF 24/344 reads (7%) | catalogued as COSV100354688; called by muse, mutect2
- CYP2S1 | c.979T>C p.W327R | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1383399493; called by muse, mutect2
- LOXHD1 | c.1717G>A p.V573I | Missense Mutation (SNP) | VAF 52/696 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as rs188554662, COSV59661682; ClinVar: uncertain significance; called by muse, mutect2
- RMC1 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1396419968; called by muse, mutect2
- FGF1 | c.161A>C p.D54A | Missense Mutation (SNP) | VAF 97/652 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- WDR48 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 57/602 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); called by muse, mutect2
- AC107023.1 | n.25+10028C>T | Intron (SNP) | VAF 40/498 reads (8%) | called by muse, mutect2
